Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6166, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6166-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

* Addendum *

....

Clinical Diagnosis & History:

with transverse colon moderately differentiated adenocarcinoma.

Specimens Submitted:

1: SP: Right colon, hemicolectomy

DIAGNOSIS:

1. LARGE BOWEL; RIGHT HEMICOLECTOMY:
- TUMOR TYPE: ADENOCARCINOMA.
- HISTOLOGIC GRADE: MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: ASCENDING COLON.
- TUMOR SIZE: LENGTH IS 5.2 CM, WIDTH IS 4.1 CM, AND DEPTH IS 0.3 CM.
- TUMOR INVASION: INVASION INTO MUSCULARIS PROPRIA.
- GROSS TUMOR PERFORATION: NOT IDENTIFIED.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: NOT IDENTIFIED.
- PERINEURAL INVASION: NOT IDENTIFIED.
- SURGICAL MARGINS (FOR COLONIC TUMORS): FREE OF TUMOR.
- POLYPS (AWAY FROM THE CARCINOMA): NOT IDENTIFIED.
- OTHER FINDINGS: THE APPENDIX CONTAINS A SMALL INCIDENTAL SCHWANNOMA (<0.5 CM).
- NON-NEOPLASTIC BOWEL: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS (AJCC 2002): pT2.
- LYMPH NODES: NUMBER WITH METASTASES: 0, NUMBER EXAMINED: 33.
- THE PATHOLOGIC STAGE IS (AJCC 2002): pN0.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

[page 2 of 3]
1). The specimen is received fresh, labeled "Right colon" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 6 cm in length and 3.5 cm in circumference at the proximal resected margin. The remaining colon measures 33 cm in length with a circumference of 7 cm at the distal resected margin. The attached appendix measures 7 cm in length and averages 0.4 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 3 cm in thickness. Attached unremarkable omental fat measures 18 x 6 x 1.3 cm. The specimen is opened to reveal a mass lesion measuring 5.2 cm in length and 4.1 cm in width. Sectioning show that the tumor invades into the muscularis. The depth of invasion is 0.3 cm grossly. The remaining mucosa is grossly unremarkable. Multiple lymph nodes are identified in the attached adipose tissue and are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P-- proximal margin shave
D -- distal margin shave
T-- mass
A -- appendix representative sections
RS--representative sections
O- omental fat
LN-- lymph nodes, 17-19 closest to tumor
ADD additional sections from tumor area (the tumor is entirely submitted now)

Summary of Sections:

Part 1: SP: Right colon, hemicolectomy

Block	Sect. Site	PCs
2	A	2
3	add	3
2	DM	2
8	LN	8
2	O	2
1	PM	1
2	RS	2
4	T	4

** Continued on next page **

[page 3 of 3]
Addendum Diagnosis

#1) SITE: LARGE BOWEL, RIGHT COLON

- IMMUNOHISTOCHEMICAL STAINING FOR DNA MISMATCH REPAIR PROTEINS HAS BEEN PERFORMED. THE RESULTS ARE AS FOLLOWS:

MLH1: STAINING PRESENT IN TUMOR

MSH2: STAINING PRESENT IN TUMOR

MSH6: STAINING PRESENT IN TUMOR

PMS2: STAINING PRESENT IN TUMOR

CONCLUSION: IMMUNOHISTOCHEMICAL STAINING FOR THE TESTED DNA MISMATCH REPAIR PROTEINS IS RETAINED IN THE TUMOR.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the department of pathology. They have not been cleared or approved by the US food and drug administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the clinical laboratory improvement amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

** End of Report **

Source: NCI Genomic Data Commons file d50b4c5e-f81c-42a2-9219-dec03f23f93b (TCGA-CM-6166.90156818-E669-4A4F-9E1A-081544E01E35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).